Somatic mutation profile of tumor specimen TARGET-20-PASXJY-09A (aliquot TARGET-20-PASXJY-09A-01D) from TARGET case TARGET-20-PASXJY, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.1 years (4,778 days).
Specimen TARGET-20-PASXJY-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) afc00443-81ba-48c6-9efb-c0918492b927.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASXJY-14A (Bone Marrow Normal), aliquot TARGET-20-PASXJY-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/167cd8ff-35e8-4f1a-a05d-991d1bbde8ea

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Missense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1783_1797dup p.R595_Y599dup | In Frame Ins (INS) | VAF 64/150 reads (43%) | catalogued as COSV54044553, COSV54063238, COSV54064115, COSV54076099; called by mutect2, varscan2
- NPM1 | c.863_864insTACG p.W288Cfs*12 | Frame Shift Ins (INS) | VAF 19/42 reads (45%) | catalogued as COSV51544444, COSV51555499, COSV51560925, COSV51570713; called by mutect2, pindel, varscan2
- SMC3 | c.382G>C p.A128P | Missense Mutation (SNP) | VAF 45/125 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
